Gene-level copy-number profile of tumor specimen C3L-04489-58 from CPTAC case C3L-04489, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 76.8 years (28,036 days).
Specimen C3L-04489-58: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 91eef6d8-89e9-4407-a166-1bb7306fcd38.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-04489-50 (buccal cell normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/bfa37718-00e1-411b-87d1-21a7ebab4b9f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 131; copy number 2: 2,910; copy number 3: 218; copy number 4: 50,949; copy number 5: 779; copy number 6: 3,066; copy number 7: 11; copy number 8: 13; copy number 10: 17; copy number 12: 12; copy number 13: 77; copy number 15: 73; copy number 16: 129; copy number 18: 7.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:38,349,849–38,363,619, 1 gene: UFM1.
- chr17:22,233,926–22,266,392, 1 gene: LINC02002.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 315 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:9,068,361–9,129,752, 1 gene, copy number 10 (within-gene range 6–10): TEKT4P2.
- chr21:9,325,013–21,797,415, 168 genes, copy number 10–18 (broad region; genes not listed).
- chr21:37,593,977–38,121,345, 2 genes, copy number 16 (within-gene range 6–16): AP001407.1, KCNJ6.
- chr21:37,951,425–44,131,181, 144 genes, copy number 12–16 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 131. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
